Somatic mutation profile of tumor specimen 0DNDZQ from CCDI case PBBXDX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Malignant peripheral nerve sheath tumor; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 14.3 years (5,211 days).
Specimen 0DNDZQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7047735-78e8-4a53-b077-d01c0de7db6b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNE0O (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65c59378-3936-4472-aec9-b166af39a929

The open-access MAF lists 39 somatic variants for this specimen: 24 protein-altering or splice-affecting, 2 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Intron 5, 3'UTR 4, RNA 2, Silent 2, Nonsense Mutation 1, 5'Flank 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY4 | c.2066C>T p.S689L | Missense Mutation (SNP) | VAF 233/564 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1207407092; called by muse, mutect2, varscan2
- C1orf116 | c.216C>G p.D72E | Missense Mutation (SNP) | VAF 278/710 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.468); catalogued as COSV63943698, COSV63943726; called by muse, mutect2, varscan2
- CARMIL2 | c.3284G>A p.R1095Q | Missense Mutation (SNP) | VAF 203/584 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs1336504683, COSV99537630; called by muse, mutect2, varscan2
- CARMIL2 | c.3383G>A p.R1128Q | Missense Mutation (SNP) | VAF 247/750 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs779712556, COSV54667201; called by muse, mutect2, varscan2
- CARMIL3 | c.2399C>T p.A800V | Missense Mutation (SNP) | VAF 56/517 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.603); catalogued as rs774345899, COSV57728187; called by muse, mutect2
- CTNNA2 | c.1450G>T p.V484F | Missense Mutation (SNP) | VAF 70/711 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.522); catalogued as COSV58163466, COSV58185382; called by muse, mutect2, varscan2
- DOK6 | c.290-1G>A p.X97_splice | Splice Site (SNP) | VAF 77/489 reads (16%) | catalogued as rs1191838037, COSV66929858; called by muse, mutect2, varscan2
- MYH13 | c.2780C>T p.T927M | Missense Mutation (SNP) | VAF 148/504 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as rs768267700; called by muse, mutect2, varscan2
- MYH3 | c.5291C>T p.A1764V | Missense Mutation (SNP) | VAF 63/398 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as rs762975920; called by muse, mutect2, varscan2
- NHS | c.4480G>A p.E1494K | Missense Mutation (SNP) | VAF 96/593 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101196514; called by muse, mutect2, varscan2
- SELP | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 338/746 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs757902140; called by muse, mutect2, varscan2
- SLC18B1 | c.1006G>A p.V336M | Missense Mutation (SNP) | VAF 98/817 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as rs757936049, COSV51594455; called by muse, mutect2, varscan2
- ADCY4 | c.1949C>T p.P650L | Missense Mutation (SNP) | VAF 146/436 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AMER1 | c.299G>A p.S100N | Missense Mutation (SNP) | VAF 112/246 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- AMPD2 | c.1441C>T p.Q481* | Nonsense Mutation (SNP) | VAF 78/611 reads (13%) | called by muse, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 50/1204 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CENPT | c.256C>A p.P86T | Missense Mutation (SNP) | VAF 76/993 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ELL2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 68/512 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MRC1 | c.568G>C p.G190R | Missense Mutation (SNP) | VAF 170/758 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PPP4R3A | c.521T>A p.L174Q | Missense Mutation (SNP) | VAF 53/1050 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PRMT8 | c.487A>G p.T163A | Missense Mutation (SNP) | VAF 24/610 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.047); called by muse, mutect2
- RPL10 | c.91A>T p.I31F | Missense Mutation (SNP) | VAF 211/455 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- RYR3 | c.2368C>G p.L790V | Missense Mutation (SNP) | VAF 64/460 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- TTC8 | c.658C>T p.H220Y | Missense Mutation (SNP) | VAF 49/824 reads (6%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.012); called by muse, mutect2
- ADAL | c.366G>A p.V122= | Silent (SNP) | VAF 76/451 reads (17%) | called by muse, mutect2, varscan2
- BPTF | c.7911G>A p.Q2637= | Silent (SNP) | VAF 124/1376 reads (9%) | called by muse, mutect2
- ABI3 | c.*30C>G | 3'UTR (SNP) | VAF 34/410 reads (8%) | called by muse, mutect2
- ADCY4 | c.2157+32C>T | Intron (SNP) | VAF 161/372 reads (43%) | called by muse, mutect2, varscan2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 26/759 reads (3%) | called by muse, mutect2
- BTF3 | c.575-53A>C | Intron (SNP) | VAF 55/467 reads (12%) | called by muse, mutect2, varscan2
- CARMIL2 | c.4117+87G>A | Intron (SNP) | VAF 73/173 reads (42%) | called by muse, mutect2, varscan2
- IL9RP4 | n.862A>G | RNA (SNP) | VAF 50/468 reads (11%) | called by muse, mutect2, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 18/324 reads (6%) | called by muse, mutect2
- LMNA | c.1969-38C>G | Intron (SNP) | VAF 52/189 reads (28%) | called by muse, mutect2, varscan2
- PLA2G4F | c.-46G>C | 5'UTR (SNP) | VAF 40/372 reads (11%) | called by muse, mutect2, varscan2
- TCTN3 | chr10:95693942 C>G | 5'Flank (SNP) | VAF 24/163 reads (15%) | catalogued as rs994396444; called by muse, mutect2, varscan2
- TERF1 | c.*46C>T | 3'UTR (SNP) | VAF 137/653 reads (21%) | called by muse, mutect2, varscan2
- TTC8 | c.459+44T>A | Intron (SNP) | VAF 30/814 reads (4%) | called by muse, mutect2
- TULP4 | c.*83C>G | 3'UTR (SNP) | VAF 24/120 reads (20%) | catalogued as rs1005171117; called by muse, mutect2, varscan2
